Somatic mutation profile of tumor specimen ALCH-B2UA-TTP1-A (aliquot ALCH-B2UA-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2UA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.4 years (25,354 days).
Specimen ALCH-B2UA-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7561e98e-6be1-4c29-a094-e0611d2a4bd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UA-NB1-A (Blood Derived Normal), aliquot ALCH-B2UA-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9efd3540-d156-4d33-af95-e4c60a75eae6

The open-access MAF lists 125 somatic variants for this specimen: 77 protein-altering or splice-affecting, 26 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 26, Intron 10, Nonsense Mutation 6, 5'UTR 3, RNA 3, Frame Shift Del 3, 3'UTR 3, 5'Flank 2, 3'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 70/575 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1832T>A p.V611E | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56642210; called by muse, mutect2
- AFF2 | c.2280G>A p.M760I | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53984786; called by muse, mutect2, varscan2
- ATM | c.6814G>A p.E2272K | Missense Mutation (SNP) | VAF 34/359 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs886039471, CM030779, COSV53744239, COSV99588352; ClinVar: uncertain significance; called by muse, mutect2
- BARD1 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV53611151; called by muse, mutect2, varscan2
- BRINP3 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100818380; called by muse, mutect2
- C3orf70 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 14/354 reads (4%) | catalogued as COSV100621382; called by muse, mutect2
- CCDC105 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as rs760693691, COSV52963515; called by muse, mutect2
- CCNP | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV55688755; called by muse, mutect2
- EIF1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV100179480; called by muse, mutect2, varscan2
- ERBB3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as rs561743080, COSV57250688; called by muse, mutect2
- EXOC4 | c.758C>G p.S253* | Nonsense Mutation (SNP) | VAF 14/144 reads (10%) | catalogued as COSV54125018; called by muse, mutect2, varscan2
- FLNA | c.1562G>A p.G521D | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); catalogued as COSV100775460; called by muse, mutect2, varscan2
- GAP43 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV59344017; called by muse, mutect2
- GORAB | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV63028247; called by muse, mutect2
- GPR15 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs534323108; called by muse, mutect2
- HCN1 | c.2528G>C p.R843P | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV57532468; called by muse, mutect2
- IL22RA2 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV51665271; called by muse, mutect2
- KLF16 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1164887918; called by muse, mutect2
- LAMA2 | c.2284C>A p.H762N | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70344808, COSV70354438; called by muse, mutect2
- MYLK | c.4460G>C p.R1487P | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV60609438; called by muse, mutect2
- NOTCH1 | c.4325del p.P1442Rfs*3 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as COSV53045529; called by pindel, varscan2
- PDF | c.25_26del p.W11Afs*151 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | catalogued as rs1567429479; called by mutect2, pindel, varscan2
- PLCB3 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV54191779; called by muse, mutect2, varscan2
- PTDSS1 | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61266762; called by muse, mutect2
- RBL1 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764221823; called by muse, mutect2
- RDH8 | c.976A>T p.T326S (on ENST00000651512; = p.T306S on NM_015725.4) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs200983402; called by muse, mutect2
- RPS6KL1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV100665218; called by muse, mutect2
- SIRPD | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 36/411 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101064904, COSV67546399; called by muse, mutect2
- TP53 | c.257del p.A86Dfs*37 | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | catalogued as COSV53771066; called by mutect2, pindel*, varscan2
- VSX2 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 34/577 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760583829; called by muse, mutect2
- ABCG4 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 31/429 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.255); called by muse, mutect2
- ABHD8 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- ACMSD | c.412T>A p.F138I | Missense Mutation (SNP) | VAF 35/851 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.204); called by muse, mutect2
- ADH1A | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 24/294 reads (8%) | called by muse, mutect2
- APBB2 | c.1741A>G p.T581A (on ENST00000295974 / NM_001166050.2; = p.T582A on NM_004307.2) | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.955); called by muse, varscan2
- AQP1 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 40/599 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ARSJ | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2
- BIRC6 | c.3913A>T p.R1305* | Nonsense Mutation (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- BPIFA2 | c.198G>C p.Q66H | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDK12 | c.1473dup p.V492Cfs*2 | Frame Shift Ins (INS) | VAF 22/180 reads (12%) | called by mutect2, pindel, varscan2
- DDIAS | c.365T>C p.V122A | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2
- GARS1 | c.1114C>A p.H372N | Missense Mutation (SNP) | VAF 21/461 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- GSX1 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); called by muse, mutect2
- HOXB8 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 58/499 reads (12%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.317G>T p.R106I | Missense Mutation (SNP) | VAF 21/430 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2
- IGHV1OR15-9 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INSM1 | c.1533G>C p.*511Yext*53 | Nonstop Mutation (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- KRIT1 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- LAMA5 | c.7106A>T p.Q2369L | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- LPAR3 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 26/527 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2
- LYG2 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- MGA | c.8074G>A p.D2692N (on ENST00000219905 / NM_001164273.1; = p.D2483N on NM_001080541.2) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC1 | c.3131C>G p.S1044C (on ENST00000611571 / NM_001371720.1; = p.S55C on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/802 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MUC16 | c.24275C>A p.T8092N | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.282); called by muse, mutect2
- MUC4 | c.12107C>G p.T4036S | Missense Mutation (SNP) | VAF 61/465 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NOTCH1 | c.4318A>T p.I1440F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR4C5 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PANX2 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PASD1 | c.2276C>A p.T759N | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.402); called by muse, mutect2
- PCDHB8 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 64/2108 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIK3CG | c.3067C>T p.H1023Y | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- PKD1L3 | c.1635G>C p.L545F | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLBD2 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2
- RASA1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- SLC12A1 | c.2776A>T p.I926F | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, varscan2
- SLC44A2 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- STYK1 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- TCERG1L | c.489+1G>C p.X163_splice | Splice Site (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- TRIM24 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRIM26 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 21/391 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- TRIR | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.375); called by muse, mutect2
- TTC17 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- TTLL2 | c.1154T>C p.L385S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UTP6 | c.514C>G p.H172D | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- XAGE5 | c.180G>T p.V60= | Splice Region (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- ZNF14 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ELFN1 | c.1491C>T p.I497= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV70035568; called by muse, mutect2
- FOXD4 | c.1059C>T p.S353= | Silent (SNP) | VAF 68/1158 reads (6%) | catalogued as rs748624690; called by muse, mutect2
- FOXM1 | c.2193C>T p.L731= | Silent (SNP) | VAF 20/301 reads (7%) | called by muse, mutect2
- GAB1 | c.1875G>A p.V625= | Silent (SNP) | VAF 15/269 reads (6%) | catalogued as COSV53759437; called by muse, mutect2
- GOLGB1 | c.8187C>T p.L2729= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as rs116030179; called by muse, mutect2, varscan2
- H2AC8 | c.234C>G p.R78= | Silent (SNP) | VAF 17/354 reads (5%) | called by muse, mutect2
- KIF26A | c.2139C>G p.L713= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100181104; called by muse, mutect2
- LRP1B | c.12039G>C p.L4013= | Silent (SNP) | VAF 16/553 reads (3%) | called by muse, mutect2
- MB21D2 | c.1386G>T p.V462= | Silent (SNP) | VAF 30/446 reads (7%) | called by muse, mutect2
- MRPS26 | c.366G>A p.A122= | Silent (SNP) | VAF 28/300 reads (9%) | catalogued as rs1044537576, COSV55662209; called by muse, mutect2
- MYO9B | c.3477C>G p.V1159= | Silent (SNP) | VAF 58/975 reads (6%) | called by muse, mutect2
- PASD1 | c.2277C>A p.T759= | Silent (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- PCDH15 | c.3204G>T p.V1068= | Silent (SNP) | VAF 56/548 reads (10%) | called by muse, mutect2
- PCNX2 | c.3021C>G p.V1007= | Silent (SNP) | VAF 31/276 reads (11%) | called by muse, mutect2, varscan2
- PDE1C | c.669C>T p.H223= | Silent (SNP) | VAF 26/368 reads (7%) | called by muse, mutect2
- PLET1 | c.201T>C p.N67= | Silent (SNP) | VAF 41/317 reads (13%) | called by muse, mutect2, varscan2
- POTEA | c.162C>T p.F54= | Silent (SNP) | VAF 34/534 reads (6%) | catalogued as rs1310755579; called by muse, mutect2
- PRG4 | c.258C>T p.C86= | Silent (SNP) | VAF 46/795 reads (6%) | catalogued as rs762328095, COSV100825683; called by muse, mutect2
- PRR12 | c.3303G>T p.G1101= (on ENST00000615927; = p.G1922= on NM_020719.3) | Silent (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- RASAL2 | c.18G>T p.S6= | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- SARDH | c.2176C>A p.R726= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV64101054; called by mutect2, varscan2
- SVOP | c.363G>A p.Q121= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- THSD7B | c.3079C>T p.L1027= | Silent (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- TMEM39B | c.1296C>T p.V432= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- TTN | c.27588T>C p.L9196= (on ENST00000591111; = p.L8269= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- VIT | c.1527C>A p.G509= (on ENST00000389975 / NM_001177969.1; = p.G524= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/219 reads (10%) | called by muse, mutect2
- CDKL5 | c.-43G>C | 5'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- CSRP3 | c.*18C>T | 3'UTR (SNP) | VAF 34/458 reads (7%) | called by muse, mutect2
- CTSW | c.-11A>G | 5'UTR (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- DYNC1LI1 | c.220+3717C>A | Intron (SNP) | VAF 10/110 reads (9%) | catalogued as rs974796946; called by mutect2, varscan2
- EHMT1 | c.2505+1118C>G | Intron (SNP) | VAF 23/193 reads (12%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1156C>A | RNA (SNP) | VAF 18/176 reads (10%) | called by muse, varscan2
- HTR5A | chr7:155070297 G>C | 5'Flank (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- IGKV3D-11 | c.-9G>T | 5'UTR (SNP) | VAF 22/362 reads (6%) | called by muse, mutect2
- MATR3 | c.-462+44G>A | Intron (SNP) | VAF 20/290 reads (7%) | catalogued as rs767281390; called by muse, mutect2
- PCDH15 | c.*20G>A | 3'UTR (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- PCDHB6 | chr5:141157529 G>A | 3'Flank (SNP) | VAF 70/880 reads (8%) | called by muse, mutect2
- PPAT | c.403-603C>T | Intron (SNP) | VAF 25/286 reads (9%) | called by muse, mutect2
- RECQL5 | chr17:75667324 C>T | 5'Flank (SNP) | VAF 13/251 reads (5%) | called by muse, mutect2
- RHOA | c.409-543G>A | Intron (SNP) | VAF 10/137 reads (7%) | called by muse, mutect2
- RIMS2 | c.4064-21141C>G | Intron (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- SIRPB1 | c.76+15099G>C | Intron (SNP) | VAF 31/402 reads (8%) | called by muse, mutect2
- SNORD116-11 | n.42G>A | RNA (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- SYNRG | c.590-1573G>A | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- WRAP73 | c.923-41G>A | Intron (SNP) | VAF 28/339 reads (8%) | catalogued as rs377544699; called by muse, mutect2
- ZC3H14 | c.80-127C>T | Intron (SNP) | VAF 14/206 reads (7%) | catalogued as rs1221583131; called by muse, mutect2
- ZNF733P | n.325T>A | RNA (SNP) | VAF 26/630 reads (4%) | called by muse, mutect2
- ZNF99 | c.*3217A>G | 3'UTR (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
